CCDI case PBBRYS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/68e1466b-855d-4d88-9b83-8cb1a2ba6c08

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.9 years (328 days).

Biospecimens (3 samples)
- Sample 0DFRTQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFRTR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFRTS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
